Surgical pathology report (de-identified scan), TCGA case TCGA-61-1741, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1741-01A (Primary Tumor).

FINAL DIAGNOSIS:

**PART 1: OMENTUM, PARTIAL RESECTION –
METASTATIC SEROUS PAPILLARY ADENOCARCINOMA.**

**PART 2: PELVIC SIDEWALL, LEFT, BIOPSY –
METASTATIC SEROUS PAPILLARY ADENOCARCINOMA.**

**PART 3: LEFT FALLOPIAN TUBE AND OVARY, LEFT SALPINGO-OOPHORECTOMY –
POORLY DIFFERENTIATED SEROUS PAPILLARY ADENOCARCINOMA WITH EXTENSION TO LEFT PERITUBAL
TISSUE.**

**PART 4: PELVIC TUMOR, BIOPSY –
METASTATIC SEROUS PAPILLARY ADENOCARCINOMA.**

**PART 5: RIGHT FALLOPIAN TUBE AND OVARY, RIGHT SALPINGO-OOPHORECTOMY –
POORLY DIFFERENTIATED SEROUS PAPILLARY ADENOCARCINOMA WITH EXTENSION TO RIGHT PERITUBAL
TISSUE.**

**PART 6: CUL DE SAC, POSTERIOR, BIOPSY –
METASTATIC SEROUS PAPILLARY ADENOCARCINOMA.**

Source: NCI Genomic Data Commons file 72d2f04d-de69-4fea-8559-79bb0adf6bb5 (TCGA-61-1741.E2D0EC41-559C-48D4-8C4D-59E0F9D48823.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).